Somatic mutation profile of tumor specimen TCGA-AG-3882-01A (aliquot TCGA-AG-3882-01A-01W-0899-10) from TCGA case TCGA-AG-3882, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.3 years (24,198 days).
Specimen TCGA-AG-3882-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74c075e3-f1df-4b13-9838-555338f1ba51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3882-10A (Blood Derived Normal), aliquot TCGA-AG-3882-10A-01W-0901-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/099b6149-f1e8-4c20-b7f8-d96a61faf0a1

The open-access MAF lists 80 somatic variants for this specimen: 64 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 15, Nonsense Mutation 3, Intron 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 187/274 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.48820C>T p.R16274* (on ENST00000591111; = p.R8850* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 55/344 reads (16%) | catalogued as rs753333359, COSV60032613; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANGPT2 | c.564C>T p.N188= | Splice Region (SNP) | VAF 28/1127 reads (2%) | catalogued as COSV100291062; called by muse, mutect2
- BRINP3 | c.1265A>T p.E422V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV100819123; called by muse, mutect2, varscan2
- CD1B | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 84/538 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.573); catalogued as COSV63805122; called by muse, mutect2, varscan2
- CD5L | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1407147417, COSV63822946; called by mutect2, varscan2
- CFAP47 | c.4967C>T p.P1656L | Missense Mutation (SNP) | VAF 258/900 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV100545568; called by muse, mutect2, varscan2
- CHRM2 | c.1341C>A p.F447L | Missense Mutation (SNP) | VAF 20/588 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100281629; called by muse, mutect2
- CNKSR2 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.711); catalogued as rs759351281, COSV99669234; called by muse, mutect2, varscan2
- CNTNAP5 | c.2234C>T p.T745I | Missense Mutation (SNP) | VAF 290/760 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV101443838; called by muse, varscan2
- COL18A1 | c.2879G>A p.R960K (on ENST00000359759 / NM_130444.3; = p.R725K on NM_030582.4) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100700815; called by muse, mutect2, varscan2
- COL5A1 | c.4754G>A p.R1585Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs531431738, COSV65667681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMT1 | c.4097C>T p.T1366M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61579594; called by muse, mutect2
- DYSF | c.4586G>A p.R1529Q | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs191383034, COSV50289003, COSV50367093; called by muse, varscan2
- EXOC3L2 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as rs753678688, COSV99374585; called by muse, mutect2, varscan2
- FBN1 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100355896; called by muse, mutect2
- FBXW4 | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.352); catalogued as COSV58709609; called by muse, mutect2, varscan2
- FMN2 | c.3724G>T p.G1242C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.961); catalogued as rs774306832, COSV60451335; called by muse, mutect2, varscan2
- FOXI1 | c.987C>A p.S329R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1233843670, COSV100089181; called by muse, mutect2, varscan2
- FREM2 | c.5257G>A p.D1753N | Missense Mutation (SNP) | VAF 70/706 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99749748; called by muse, mutect2, varscan2
- GK2 | c.788C>A p.A263E | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62628261; called by muse, mutect2, varscan2
- GSK3B | c.961C>A p.L321M (on ENST00000264235 / NM_001146156.2; = p.L334M on NM_002093.4) | Missense Mutation (SNP) | VAF 82/412 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51782060; called by muse, mutect2, varscan2
- IL27RA | c.1325G>T p.R442M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV99652281; called by muse, mutect2
- KLF12 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs375091947; called by muse, mutect2, varscan2
- LACTB | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 304/469 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs566925626, COSV56055776; called by muse, mutect2, varscan2
- LIPE | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs750527152, COSV54923796; called by muse, mutect2, varscan2
- LRP1B | c.11830G>C p.G3944R | Missense Mutation (SNP) | VAF 30/884 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101258310; called by muse, mutect2
- LRRK2 | c.5467C>A p.Q1823K | Missense Mutation (SNP) | VAF 226/521 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs72547980, CM097543; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MAGEA12 | c.744A>C p.Q248H | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV100756767, COSV63294236; called by muse, mutect2, varscan2
- MASP1 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs115241263; called by muse, mutect2, varscan2
- MCF2 | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 530/1846 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100644931; called by muse, mutect2, varscan2
- MFSD14B | c.1399G>A p.G467S | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs199783937; called by muse, mutect2, varscan2
- MRC2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.38); catalogued as rs370889422, COSV57643896; called by muse, mutect2, varscan2
- MRPS36 | c.10A>G p.S4G | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV56508456; called by muse, mutect2, varscan2
- MYO3B | c.1471C>A p.R491S | Missense Mutation (SNP) | VAF 15/353 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58715774; called by muse, mutect2
- NELL2 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs141156235, COSV61575927; called by muse, mutect2, varscan2
- NXF1 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.609); catalogued as rs779393008, COSV53676383; called by muse, mutect2, varscan2
- OXGR1 | c.398G>A p.C133Y | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100037065; called by muse, mutect2
- PASD1 | c.1657A>G p.M553V | Missense Mutation (SNP) | VAF 114/224 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV64857444; called by muse, mutect2, varscan2
- PHLDB2 | c.2930G>A p.R977H (on ENST00000393925 / NM_001134439.2; = p.R934H on NM_145753.2) | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs748340744, COSV67312165; called by muse, mutect2, varscan2
- PIWIL1 | c.1295A>G p.D432G | Missense Mutation (SNP) | VAF 124/488 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs983785533, COSV55351368; called by muse, mutect2, varscan2
- PRDM1 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); catalogued as rs762241140, COSV64846343; called by muse, mutect2, varscan2
- RFX7 | c.4055A>C p.E1352A (on ENST00000559447 / NM_001368074.1; = p.E1449A on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57968323; called by muse, mutect2
- RNFT2 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs571206253, COSV57484982; called by muse, varscan2
- SERBP1 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100769107, COSV100769143; called by muse, mutect2, varscan2
- SIGLEC14 | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs781491618, COSV99707712; called by mutect2, varscan2
- SLC1A2 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 38/165 reads (23%) | catalogued as COSV53521197; called by muse, mutect2, varscan2
- SORCS3 | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 120/569 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs766974726, COSV100863417; called by muse, mutect2, varscan2
- SPTA1 | c.3514G>T p.A1172S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs767818064, COSV100935578; called by muse, mutect2, varscan2
- SSB | c.1039C>A p.Q347K | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99641803; called by muse, mutect2, varscan2
- STAG3 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV99444898; called by muse, mutect2
- STYXL2 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99609560; called by muse, mutect2, varscan2
- SYT16 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 216/388 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs190756776, COSV101413659, COSV70855911; called by muse, mutect2, varscan2
- TACR3 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 78/561 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs200736098, COSV59200720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF7L2 | c.1462C>T p.R488C (on ENST00000355995 / NM_001367943.1; = p.R465C on NM_030756.5) | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1264066389, COSV53335962, COSV53336193; called by muse, mutect2, varscan2
- TGM6 | c.424+2T>G p.X142_splice | Splice Site (SNP) | VAF 29/103 reads (28%) | catalogued as COSV99171955; called by muse, mutect2, varscan2
- TLR8 | c.1990G>A p.A664T (on ENST00000218032 / NM_138636.5; = p.A682T on NM_016610.4) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.129); catalogued as COSV99487155; called by muse, mutect2, varscan2
- TTC29 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 106/496 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV57275027; called by muse, mutect2, varscan2
- TTN | c.25272G>T p.K8424N (on ENST00000591111; = p.K7497N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/139 reads (36%) | PolyPhen benign (0.297); catalogued as COSV59875828; called by muse, mutect2, varscan2
- VCAN | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV99426632; called by muse, mutect2
- WNT2 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.124); catalogued as rs779778873, COSV55410380; called by muse, mutect2, varscan2
- ZNF235 | c.1406G>C p.S469T | Missense Mutation (SNP) | VAF 110/305 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); catalogued as COSV52158319; called by muse, mutect2, varscan2
- APC | c.1742dup p.E582Gfs*20 | Frame Shift Ins (INS) | VAF 267/590 reads (45%) | called by mutect2, pindel, varscan2
- TRGV4 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 117/325 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- AADACL4 | c.639C>T p.P213= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV66107096; called by muse, mutect2, varscan2
- CCZ1 | c.309C>T p.V103= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs1181576231, COSV58075367; called by muse, mutect2, varscan2
- CPZ | c.402C>T p.D134= (on ENST00000360986 / NM_001014447.3; = p.D123= on NM_003652.3) | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs143569240; called by muse, varscan2
- DOCK1 | c.3558C>A p.T1186= | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as COSV54756593, COSV54757880; called by muse, mutect2
- EMILIN2 | c.375C>T p.P125= | Silent (SNP) | VAF 38/74 reads (51%) | catalogued as rs759403891, COSV54427077; called by muse, mutect2, varscan2
- FBXW4 | c.1224C>T p.S408= | Silent (SNP) | VAF 90/210 reads (43%) | catalogued as COSV58709596; called by muse, mutect2, varscan2
- GRIK1 | c.486G>A p.L162= | Silent (SNP) | VAF 27/305 reads (9%) | catalogued as COSV100517398; called by muse, mutect2
- ITGAL | c.2580T>A p.S860= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as COSV63324135; called by muse, mutect2, varscan2
- MTHFD1 | c.2529C>T p.P843= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as rs1369613607, COSV53703421, COSV99386677; called by muse, mutect2, varscan2
- MYCT1 | c.240G>A p.L80= | Silent (SNP) | VAF 112/254 reads (44%) | catalogued as COSV65891752; called by mutect2, varscan2
- PRKCG | c.624G>A p.T208= | Silent (SNP) | VAF 70/165 reads (42%) | catalogued as rs553245210, COSV54723946; called by muse, mutect2, varscan2
- PTCD1 | c.1155G>A p.E385= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99464197; called by muse, mutect2
- PTPRT | c.3795C>T p.F1265= | Silent (SNP) | VAF 40/201 reads (20%) | catalogued as rs376065743, COSV61987955; called by muse, mutect2, varscan2
- ZMYM2 | c.3993C>T p.C1331= | Silent (SNP) | VAF 168/469 reads (36%) | catalogued as rs370286795; called by muse, mutect2, varscan2
- ZNF382 | c.90G>A p.A30= | Silent (SNP) | VAF 91/264 reads (34%) | catalogued as rs763656165, COSV53091847; called by muse, mutect2, varscan2
- VGLL4 | c.65-41445A>C | Intron (SNP) | VAF 146/341 reads (43%) | catalogued as COSV56081428; called by muse, mutect2, varscan2
